Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A8FS, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A8FS-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN FORTY ONE (41) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN TWENTY EIGHT (28) LYMPH NODES EXAMINED.

PART 3: SOFT TISSUE, ANTERIOR FAT PAD, EXCISION -
BENIGN FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.

PART 4: URETHRA, URETHRAL STUMP, BIOPSY -
BENIGN PROSTATIC TISSUE, NEGATIVE FOR MALIGNANCY.

Per TSS, Gleason is 4+4=8

PART 5: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 WITH TERTIARY GLEASON PATTERN 5 AND FOCAL DUCTAL FEATURES.
B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.8 CM.
C. THE CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
D. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION.
E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE ANTERIOR LEFT APEX REGION (SLIDE 5T).
F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
G. ALTHOUGH ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA, THE TUMOR IS VERY CLOSE (LESS THAN 0.1 CM) IN THE REGION OF POSTERIOR LEFT APEX (SLIDE 5C).
H. PERINEURAL INVASION IS IDENTIFIED.
I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
J. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
K. PATHOLOGIC TNM STAGE: pT3a NO MX.
L. TNM HISTOLOGIC GRADE = G3.
M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 6: DISTAL URETHRA, URETHRAL STUMP, BIOPSY -
A. BENIGN FIBROADIPOSE TISSUE.
B. NO PROSTATIC TISSUE SEEN.
C. NEGATIVE FOR MALIGNANCY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS
CLINICAL DATA: PSA value: 7.5
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 40%
WEIGHT OF PROSTATE: 49.85gm
TUMOR SIZE: Maximum dimension: 1.8 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: Yes - Focal
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 69
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICD-O-3
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
94011/28/13

Primary Malignancy History		☒

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Prostate adenocarcinoma	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	invasive prostatic adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	ductal	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	specimen submitted has a different gleason score	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

GLEASON SCORE OF TISSUE SUBMITTED IS 4+4=8
GLEASON SCORE OF CASE IS 3+4=7

Source: NCI Genomic Data Commons file 4e8cf248-891a-45ec-9438-fa5ddc628667 (TCGA-EJ-A8FS.18FF4FBA-0D6B-44D5-B5B5-68CD8DADF716.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).